Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8575, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8575-01A (Primary Tumor).

Supplement diagnosis:

Most cancerous cell cells proved cytokeratin 7-positive

Assistant:

Histopathological Diagnosis:

Examination performed on

Stomach adenocarcinoma, partly tubular, mucous and solid. Metastases to regional lymph nodes with invaded capsule and perilymphatic tissue (No VI/XV) G3, pT3, pN2.

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 16 x 15 cm with the omentum sized 14 x 7.2 cm. Tumour with ulceration sized 8 x 5 x 2 cm in the lesser curvature region. Gastric lumen filled with blood clots and mucosa.

Macroscopically, the proliferation covers the muscular membrane and perigastric fat tissue. Distance from the proximal end: 2 cm, from distal end: 6.5 cm.

Microscopic description:

Adenocarcinoma tubuläre partim mucinosum partim solidum (G3).

Infiltratio carcinomatosa profunda parietis ventriculi, teale adiposae curvaturae minoris et telae subserosae.

(intestinal type acc. to Lauren's class.). Proximal and distal borders free of cancer. The omentum free of neoplastic lesions. Lymph nodes:

(periostic) (L, M, N) - metastases carcinomatosae in lymphonodis No (II/IV). Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

(lesser curvature) (P,R) - metastases carcinomatosae in lymphonodo No (W), (greater curvature) (U,W,Y) - metastases carcinomatosae in lymphonodis No (IIW). Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

Result of immunohistochemical examination

HER2 protein stained with Ventana Rabbit Antibody.

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file fa8e741f-54d5-44f9-a1b8-f70c76d4d4f6 (TCGA-D7-8575.10720B80-6A69-40F9-968F-1CF3DFE84380.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).